Somatic mutation profile of tumor specimen TCGA-32-5222-01A (aliquot TCGA-32-5222-01A-01D-1486-08) from TCGA case TCGA-32-5222, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.1 years (24,134 days).
Specimen TCGA-32-5222-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a08d135-53cd-44de-8012-f2a0d9ac68a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-32-5222-10A (Blood Derived Normal), aliquot TCGA-32-5222-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a6289cb-5343-41ad-a992-05a5e3314a0a

The open-access MAF lists 68 somatic variants for this specimen: 49 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 18, Nonsense Mutation 2, Frame Shift Del 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLEC | c.9415C>T p.R3139* (on ENST00000322810 / NM_201380.4; = p.R3029* on NM_000445.5) | Nonsense Mutation (SNP) | VAF 47/107 reads (44%) | catalogued as rs137853161, CM050309, COSV59632384; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 91/148 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121909218, CM115947, CM971272, COSV64289566, COSV64291659; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM28 | c.694T>C p.F232L | Missense Mutation (SNP) | VAF 96/239 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as COSV56101056; called by muse, mutect2, varscan2
- ALX4 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.028); catalogued as rs1270999638, COSV61326667; called by muse, mutect2, varscan2
- ARFGEF2 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.651); catalogued as COSV64212574; called by muse, mutect2, varscan2
- BNC1 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 80/196 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61756378; called by muse, mutect2, varscan2
- CCDC113 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); catalogued as rs375219394, COSV54685725; called by muse, mutect2, varscan2
- CCDC124 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101506500, COSV71490395; called by muse, mutect2, varscan2
- CEP68 | c.235C>T p.H79Y | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53125134; called by muse, mutect2, varscan2
- DMD | c.5249G>A p.R1750K | Missense Mutation (SNP) | VAF 91/115 reads (79%) | SIFT tolerated (0.06); PolyPhen benign (0.279); catalogued as COSV63757322; called by muse, mutect2, varscan2
- DPPA5 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV64875611; called by muse, mutect2, varscan2
- FLCN | c.1189G>A p.V397M | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs752006809, COSV53259578; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLG2 | c.4333C>T p.Q1445* | Nonsense Mutation (SNP) | VAF 262/951 reads (28%) | catalogued as COSV66169044; called by muse, mutect2, varscan2
- GABRA3 | c.37A>G p.S13G | Missense Mutation (SNP) | VAF 154/192 reads (80%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.003); catalogued as COSV64799152; called by muse, mutect2, varscan2
- HEMGN | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 181/516 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as rs1451210817, COSV52326091; called by muse, mutect2, varscan2
- IL18RAP | c.579G>A p.K193= | Splice Region (SNP) | VAF 59/185 reads (32%) | catalogued as COSV51826271; called by muse, mutect2, varscan2
- KRT8 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 89/285 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.175); catalogued as rs746043558, COSV53177425; called by muse, mutect2, varscan2
- LYPD4 | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs369563100; called by muse, mutect2, varscan2
- MAP1A | c.5227C>T p.R1743W | Missense Mutation (SNP) | VAF 70/205 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.319); catalogued as rs201586108, COSV55809247; called by muse, mutect2, varscan2
- OR10C1 | c.662G>T p.R221L (on ENST00000622521; = p.R219L on NM_013941.3) | Missense Mutation (SNP) | VAF 200/547 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as COSV65822383, COSV65822987; called by muse, mutect2, varscan2
- OR13C3 | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 115/291 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145157195, COSV66165876; called by muse, mutect2, varscan2
- OR13C8 | c.103T>C p.Y35H | Missense Mutation (SNP) | VAF 236/621 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1285465792, COSV58611286; called by muse, mutect2, varscan2
- PAMR1 | c.2021C>T p.P674L (on ENST00000619888 / NM_001001991.3; = p.P691L on NM_015430.4) | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs201029324, COSV53512693; called by muse, mutect2, varscan2
- PCDH17 | c.1153G>A p.G385R | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1433069558, COSV64972699; called by muse, mutect2
- PCDH19 | c.1642A>G p.T548A | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746112000, COSV55263731; called by muse, mutect2
- PCDHA13 | c.1663G>A p.V555M | Missense Mutation (SNP) | VAF 77/240 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56505482; called by muse, mutect2, varscan2
- PCDHGA8 | c.1990G>A p.V664M | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.737); catalogued as rs143444747; called by muse, mutect2, varscan2
- PCSK6 | c.1258T>C p.S420P | Missense Mutation (SNP) | VAF 70/217 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59341018; called by muse, mutect2, varscan2
- PHLDB3 | c.54A>C p.E18D | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV52669723; called by muse, varscan2
- PIH1D2 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 59/105 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1047422431, COSV54775531; called by muse, mutect2, varscan2
- RCBTB2 | c.1473T>A p.N491K | Missense Mutation (SNP) | VAF 7/173 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60650270; called by muse, mutect2
- RYR1 | c.7585G>A p.D2529N | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs773050889, CM122394, COSV62098415; called by muse, mutect2, varscan2
- SERPINI1 | c.317T>C p.M106T | Missense Mutation (SNP) | VAF 90/234 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV55511067; called by muse, mutect2, varscan2
- SIGLEC6 | c.527C>T p.T176M | Missense Mutation (SNP) | VAF 85/307 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as rs780557269, COSV58431654; called by muse, mutect2, varscan2
- SLX4IP | c.1163A>G p.E388G | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs1456046061, COSV57947072; called by muse, mutect2, varscan2
- SOHLH2 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.263); catalogued as COSV65901217; called by muse, mutect2, varscan2
- SPTA1 | c.2313G>C p.L771F | Missense Mutation (SNP) | VAF 130/241 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63753855; called by muse, mutect2, varscan2
- ST14 | c.930C>A p.N310K | Missense Mutation (SNP) | VAF 89/295 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV53833500; called by muse, mutect2, varscan2
- ST18 | c.2467G>A p.G823S | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV52495093; called by muse, mutect2, varscan2
- SUCLG1 | c.957G>T p.Q319H | Missense Mutation (SNP) | VAF 135/323 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV67265225; called by muse, mutect2, varscan2
- TBC1D8 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs759875939, COSV65212811; called by muse, mutect2, varscan2
- TDRD6 | c.872C>T p.T291M | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as rs763840866, COSV60175978; called by muse, mutect2, varscan2
- UBQLN3 | c.1771C>T p.L591F | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT tolerated (0.75); PolyPhen benign (0.01); catalogued as COSV61163502, COSV61164365; called by muse, mutect2, varscan2
- USH2A | c.5273A>G p.N1758S | Missense Mutation (SNP) | VAF 122/470 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.926); catalogued as rs767820497, COSV100234841, COSV56342971, COSV56374871; called by muse, mutect2, varscan2
- USP12 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs759422176, COSV56654994; called by muse, mutect2, varscan2
- ZFP64 | c.838G>A p.V280M | Missense Mutation (SNP) | VAF 38/157 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as COSV53799631, COSV99402655; called by muse, mutect2, varscan2
- ZNF280A | c.1164G>T p.K388N | Missense Mutation (SNP) | VAF 99/260 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749317439, COSV57480719; called by muse, mutect2, varscan2
- ZNF330 | c.878C>T p.T293I | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV53707451, COSV53708395; called by muse, mutect2, varscan2
- RCC1 | c.139del p.Q47Sfs*8 | Frame Shift Del (DEL) | VAF 56/240 reads (23%) | called by mutect2, pindel, varscan2
- ARFGEF2 | c.1704G>A p.V568= | Silent (SNP) | VAF 62/117 reads (53%) | catalogued as rs1397575088, COSV64212577; called by muse, mutect2, varscan2
- CD8B | c.528G>C p.L176= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV58926235; called by muse, mutect2, varscan2
- CDH7 | c.2052G>A p.R684= | Silent (SNP) | VAF 80/352 reads (23%) | catalogued as rs267605240, COSV59886961; called by muse, mutect2, varscan2
- DOCK3 | c.5637C>T p.D1879= | Silent (SNP) | VAF 82/247 reads (33%) | catalogued as rs782753395, COSV56523573; called by muse, mutect2, varscan2
- EFCAB13 | c.1755C>T p.F585= | Silent (SNP) | VAF 87/293 reads (30%) | catalogued as COSV100516312, COSV58948980; called by muse, mutect2, varscan2
- HECW1 | c.1632G>A p.T544= | Silent (SNP) | VAF 32/172 reads (19%) | catalogued as rs768142577, COSV101224174, COSV67830395; called by muse, mutect2, varscan2
- IL1R2 | c.1158A>G p.L386= | Silent (SNP) | VAF 55/146 reads (38%) | catalogued as rs946097202, COSV60207343; called by muse, mutect2, varscan2
- IRS1 | c.3447G>A p.V1149= | Silent (SNP) | VAF 60/156 reads (38%) | catalogued as rs946459210, COSV59336662; called by muse, mutect2, varscan2
- KLK15 | c.315C>T p.N105= | Silent (SNP) | VAF 79/238 reads (33%) | catalogued as rs369380000, COSV56826422; called by muse, mutect2, varscan2
- KRT71 | c.1398C>T p.G466= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV99922310; called by muse, mutect2, varscan2
- PCDH17 | c.2049G>A p.S683= | Silent (SNP) | VAF 112/270 reads (41%) | catalogued as rs972459527, COSV64974519; called by muse, mutect2, varscan2
- PCLO | c.4287T>C p.D1429= | Silent (SNP) | VAF 60/259 reads (23%) | catalogued as COSV61637530; called by muse, mutect2, varscan2
- PRODH2 | c.606G>A p.A202= (on ENST00000301175; = p.A126= on NM_021232.2 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 59/287 reads (21%) | catalogued as rs917246131, COSV56559965; called by muse, mutect2, varscan2
- RPS26 | c.141C>T p.A47= | Silent (SNP) | VAF 34/162 reads (21%) | catalogued as COSV56268562; called by muse, mutect2, varscan2
- SPOCK3 | c.1221T>C p.D407= | Silent (SNP) | VAF 44/115 reads (38%) | catalogued as COSV62726525; called by muse, mutect2, varscan2
- TBL3 | c.618C>T p.D206= | Silent (SNP) | VAF 48/113 reads (42%) | catalogued as rs199830238; called by muse, mutect2, varscan2
- TMEM63B | c.2343G>A p.V781= | Silent (SNP) | VAF 58/158 reads (37%) | catalogued as COSV52479313; called by muse, mutect2, varscan2
- TSPAN8 | c.645A>G p.G215= | Silent (SNP) | VAF 46/178 reads (26%) | catalogued as COSV56078738; called by muse, mutect2, varscan2
- MYCBP2 | c.8026+2884_8026+2887del | Intron (DEL) | VAF 17/64 reads (27%) | called by mutect2, pindel, varscan2
